Somatic mutation profile of tumor specimen MBCProject_0857_T1_WES (aliquot MBCProject_0857_T1_WES_1) from CMI case MBCProject_0857, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 35.6 years (13,014 days).
Specimen MBCProject_0857_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a13c8310-9a30-4943-b519-35ed6637af0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0857_SALIVA (Saliva), aliquot MBCProject_0857_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39d045b0-d9bc-4162-ba29-20f198d7c4af

The open-access MAF lists 85 somatic variants for this specimen: 59 protein-altering or splice-affecting, 21 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 21, Nonsense Mutation 6, 3'Flank 2, Splice Site 1, In Frame Ins 1, RNA 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PANK3 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 9/63 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs77612793; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 122/494 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs766949011, COSV50755296; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2692C>T p.R898C | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs1365894708, COSV65894461; called by muse, mutect2, varscan2
- AOAH | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 19/103 reads (18%) | catalogued as COSV51746756, COSV51748031; called by muse, mutect2, varscan2
- CDS1 | c.309C>G p.I103M | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as COSV55686805; called by muse, mutect2
- CDYL | c.643G>A p.E215K (on ENST00000328908 / NM_001368125.1; = p.E161K on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/388 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs573123342, COSV59359409; called by muse, mutect2
- CRMP1 | c.75C>G p.I25M | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV61478972; called by muse, mutect2, varscan2
- DMD | c.5413G>T p.V1805L | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as CD068545; called by muse, mutect2, varscan2
- DNAJC16 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs370451143; called by muse, mutect2, varscan2
- ECI1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100066463; called by muse, mutect2, varscan2
- EP300 | c.5515G>A p.G1839S | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.827); catalogued as COSV99609985; called by muse, mutect2, varscan2
- FBN3 | c.247G>C p.V83L | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as rs532677935; called by muse, mutect2, varscan2
- FLG | c.6769G>C p.E2257Q | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV64247458; called by muse, mutect2
- FOXC1 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 41/367 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs1294226013; called by muse, mutect2, varscan2
- GAB3 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as rs1242626854, COSV65819160; called by muse, mutect2, varscan2
- GABRA5 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 44/181 reads (24%) | catalogued as COSV59475659; called by muse, mutect2, varscan2
- GPR50 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV54437418; called by muse, mutect2, varscan2
- HEATR5A | c.5042G>C p.G1681A | Missense Mutation (SNP) | VAF 126/366 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs954216097; called by muse, mutect2, varscan2
- KANK4 | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as rs1422115373; called by muse, varscan2
- KMT2E | c.3850G>C p.E1284Q | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs1368934185; called by muse, mutect2, varscan2
- LGALS8 | c.604G>T p.V202F (on ENST00000341872; = p.V244F on NM_006499.4) | Missense Mutation (SNP) | VAF 17/388 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV99436827; called by muse, mutect2
- LRCH4 | c.308T>G p.L103R | Missense Mutation (SNP) | VAF 74/379 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53823418; called by muse, mutect2, varscan2
- MUC17 | c.2974C>T p.H992Y | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV60299186; called by muse, mutect2, varscan2
- PABPC1 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 110/360 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs747152709, COSV59408229; called by muse, mutect2, varscan2
- PLCB3 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs760018421; called by muse, mutect2, varscan2
- RBM33 | c.2513C>T p.P838L | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.443); catalogued as rs761167847; called by muse, mutect2, varscan2
- RGS21 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV69881550; called by muse, mutect2, varscan2
- RGS9 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 115/424 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as rs1271937692, COSV99287630; called by muse, mutect2, varscan2
- WDR45B | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 101/571 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as rs771755275; called by muse, mutect2, varscan2
- ZFP41 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs781397393; called by muse, mutect2, varscan2
- ZNF169 | c.10G>T p.G4* | Nonsense Mutation (SNP) | VAF 30/162 reads (19%) | catalogued as COSV61763983; called by muse, mutect2, varscan2
- ZNF853 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 61/301 reads (20%) | catalogued as COSV101499468; called by muse, mutect2, varscan2
- ZNF91 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs754774636, COSV56079585; called by muse, mutect2, varscan2
- ZSWIM1 | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV99055653; called by muse, mutect2, varscan2
- BTN3A2 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CACNA1E | c.4690-1G>T p.X1564_splice | Splice Site (SNP) | VAF 13/48 reads (27%) | called by muse, varscan2
- DBR1 | c.1615G>C p.D539H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, varscan2
- FAM177A1 | c.32G>T p.R11L (on ENST00000382406 / NM_001289022.2; = p.R34L on NM_173607.5) | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FAXC | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 81/369 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- FIG4 | c.1430_1434+7dup | In Frame Ins (INS) | VAF 60/194 reads (31%) | called by mutect2, varscan2
- FLYWCH1 | c.595T>G p.L199V (on ENST00000253928 / NM_001308068.2; = p.L198V on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- HEATR5A | c.4963G>C p.E1655Q | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- HS3ST3A1 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); called by muse, mutect2
- LAMC3 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- LONRF2 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 38/164 reads (23%) | called by muse, mutect2, varscan2
- MAST1 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, mutect2
- NAXE | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- POM121 | c.3689C>T p.S1230F (on ENST00000434423; = p.S965F on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PPP1R12A | c.1436C>G p.S479C | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); called by muse, mutect2
- SERPIND1 | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 25/420 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.639); called by muse, mutect2
- SIGLEC6 | c.167C>G p.T56S | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLC26A8 | c.1329G>A p.M443I | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TBCK | c.1219G>A p.D407N (on ENST00000273980 / NM_001163436.4; = p.D344N on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, varscan2
- TCP11L2 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); called by muse, mutect2
- TTN | c.30022G>C p.E10008Q (on ENST00000591111; = p.E9081Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/252 reads (8%) | PolyPhen benign (0.147); called by muse, mutect2
- UNC80 | c.4918C>G p.Q1640E | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.954); called by muse, mutect2
- VPS45 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.097); called by muse, mutect2
- ZNF837 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ANKMY1 | c.478C>T p.L160= | Silent (SNP) | VAF 81/456 reads (18%) | called by muse, mutect2, varscan2
- ATG2A | c.2872C>T p.L958= | Silent (SNP) | VAF 31/161 reads (19%) | called by muse, mutect2, varscan2
- C17orf78 | c.102C>T p.I34= | Silent (SNP) | VAF 36/432 reads (8%) | called by muse, mutect2
- CEP250 | c.348G>A p.V116= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as COSV100699139, COSV61172296; called by muse, varscan2
- CLIC6 | c.1527G>A p.V509= (on ENST00000360731 / NM_001317009.2; = p.V491= on NM_053277.3) | Silent (SNP) | VAF 21/204 reads (10%) | called by muse, mutect2, varscan2
- COL12A1 | c.1098C>T p.V366= | Silent (SNP) | VAF 28/332 reads (8%) | called by muse, mutect2
- COL6A5 | c.4912C>T p.L1638= | Silent (SNP) | VAF 18/190 reads (9%) | catalogued as COSV55206214; called by muse, mutect2
- CYHR1 | c.120C>T p.F40= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs771274236; called by muse, varscan2
- HDLBP | c.909G>A p.K303= | Silent (SNP) | VAF 28/345 reads (8%) | called by muse, mutect2
- IFT80 | c.1692G>A p.V564= | Silent (SNP) | VAF 59/224 reads (26%) | called by muse, mutect2, varscan2
- KCNQ5 | c.1563C>A p.V521= | Silent (SNP) | VAF 32/192 reads (17%) | called by muse, varscan2
- LRRTM4 | c.987C>T p.F329= | Silent (SNP) | VAF 24/80 reads (30%) | called by muse, mutect2, varscan2
- OR51I2 | c.261C>T p.L87= | Silent (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- PLIN5 | c.378C>T p.V126= | Silent (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- PREB | c.438G>A p.A146= | Silent (SNP) | VAF 60/643 reads (9%) | catalogued as rs778349454, COSV53205951; called by muse, mutect2
- SLC23A1 | c.1020C>T p.Y340= | Silent (SNP) | VAF 47/209 reads (22%) | catalogued as rs776506562, COSV100811901; called by muse, mutect2, varscan2
- TGM4 | c.1887C>T p.I629= | Silent (SNP) | VAF 51/188 reads (27%) | called by muse, mutect2, varscan2
- TKTL2 | c.1215A>T p.R405= | Silent (SNP) | VAF 52/351 reads (15%) | called by muse, mutect2, varscan2
- TRDN | c.1074C>T p.T358= | Silent (SNP) | VAF 28/193 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.37503G>A p.L12501= (on ENST00000591111; = p.L5077= on NM_003319.4) | Silent (SNP) | VAF 37/196 reads (19%) | catalogued as COSV59941829; called by muse, mutect2, varscan2
- XKR4 | c.1596C>G p.A532= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV59326595; called by muse, mutect2, varscan2
- ADCK2 | chr7:140695779 del CA | 3'Flank (DEL) | VAF 13/84 reads (15%) | catalogued as rs761766469; called by pindel, varscan2
- AL132655.6 | chr20:58840058 C>G | 5'Flank (SNP) | VAF 22/218 reads (10%) | catalogued as COSV58331705; called by muse, mutect2
- C16orf91 | c.32+28G>A | Intron (SNP) | VAF 19/158 reads (12%) | called by muse, mutect2, varscan2
- ENTPD5 | chr14:73959137 G>A | 3'Flank (SNP) | VAF 92/343 reads (27%) | catalogued as rs769879475; called by muse, mutect2, varscan2
- GVINP1 | n.7129G>C | RNA (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
